Somatic mutation profile of tumor specimen TCGA-DK-AA77-01A (aliquot TCGA-DK-AA77-01A-11D-A391-08) from TCGA case TCGA-DK-AA77, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 61.2 years (22,365 days).
Specimen TCGA-DK-AA77-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 193fc5c9-446a-4e11-b429-795095578b80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-AA77-10A (Blood Derived Normal), aliquot TCGA-DK-AA77-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e16c8d3-4dc1-47aa-8789-8e5e092e4b16

The open-access MAF lists 428 somatic variants for this specimen: 306 protein-altering or splice-affecting, 110 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 268, Silent 110, Nonsense Mutation 19, Splice Site 13, Intron 6, 5'UTR 4, Splice Region 3, RNA 1, Frame Shift Ins 1, Frame Shift Del 1, 5'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PAH | c.441+1G>A p.X147_splice | Splice Site (SNP) | VAF 20/70 reads (29%) | catalogued as rs62517166, CS139535, CS951498; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.993+1G>T p.X331_splice | Splice Site (SNP) | VAF 33/37 reads (89%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAK1 | c.2139C>G p.N713K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV68646423; called by muse, mutect2, varscan2
- ABCB1 | c.3254G>A p.R1085Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201765972; called by muse, mutect2, varscan2
- ABCD2 | c.1426C>T p.H476Y | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1317851870, COSV58054689; called by muse, mutect2, varscan2
- ABLIM1 | c.2313G>C p.M771I | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV53314974; called by muse, mutect2, varscan2
- ACLY | c.97C>G p.R33G | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as rs148951948, COSV61252705; called by muse, mutect2, varscan2
- ACSL5 | c.1218+1G>T p.X406_splice (on ENST00000354273; = p.X462_splice on NM_016234.3) | Splice Site (SNP) | VAF 13/51 reads (25%) | catalogued as COSV61133231; called by muse, mutect2, varscan2
- ADAMTS14 | c.3067G>A p.G1023R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as COSV64605917; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2448T>A p.D816E | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV55006759; called by muse, mutect2
- ADH1A | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs781658187, COSV52925975; called by muse, mutect2, varscan2
- ADPRH | c.887C>A p.A296D | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63695111, COSV63695712; called by muse, mutect2, varscan2
- AGPAT4 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1380831405, COSV57250483; called by muse, mutect2, varscan2
- AGTPBP1 | c.1249G>A p.E417K (on ENST00000357081 / NM_001330701.2; = p.E377K on NM_015239.2) | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as rs1286271118, COSV61276764; called by muse, mutect2, varscan2
- AHSG | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1404855873, COSV56609183; called by muse, mutect2, varscan2
- AKR1B15 | c.793A>G p.I265V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.458); catalogued as COSV71152720; called by muse, mutect2, varscan2
- ALB | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV55739218, COSV55741955; called by muse, mutect2, varscan2
- ALG11 | c.820T>C p.C274R | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV73000797; called by muse, mutect2, varscan2
- ALKBH8 | c.391C>G p.Q131E | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52838138; called by muse, mutect2, varscan2
- ANP32A | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as COSV51189904; called by muse, mutect2, varscan2
- ARHGAP32 | c.6004A>T p.S2002C (on ENST00000310343 / NM_001378025.1; = p.S1653C on NM_014715.4) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.237); catalogued as COSV59854963; called by muse, mutect2, varscan2
- ATAD2B | c.2192C>A p.T731N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.139); catalogued as rs1170827041, COSV53204611; called by muse, mutect2, varscan2
- ATP11A | c.1783C>T p.R595* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as rs760997483, COSV99367048; called by muse, mutect2, varscan2
- B4GALNT3 | c.1730G>A p.R577K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as COSV56756668, COSV56757424; called by muse, mutect2, varscan2
- BAHCC1 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as COSV100311895, COSV57032672; called by muse, mutect2, varscan2
- BARHL2 | c.914C>G p.S305W | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64981012, COSV64981943; called by muse, mutect2, varscan2
- BAZ1B | c.4153G>A p.D1385N | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59994180; called by muse, mutect2, varscan2
- BBS2 | c.1438C>G p.R480G | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as CM111288, COSV55328347; called by muse, mutect2, varscan2
- BCHE | c.1610G>A p.R537K | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52261729; called by muse, mutect2, varscan2
- BCL10 | c.216A>C p.L72F | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65354309; called by muse, mutect2, varscan2
- BTN1A1 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV55069468; called by muse, mutect2, varscan2
- C1QTNF1 | c.410C>A p.P137H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59263836; called by muse, mutect2, varscan2
- C2CD6 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as rs776476421, COSV53796858; called by muse, mutect2, varscan2
- C4orf50 | c.545G>T p.W182L (on ENST00000324058; = p.W1414L on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as COSV60690374; called by muse, mutect2, varscan2
- C9orf43 | c.152-1G>A p.X51_splice | Splice Site (SNP) | VAF 16/28 reads (57%) | catalogued as COSV55913983; called by muse, mutect2, varscan2
- C9orf72 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV66155101; called by muse, mutect2, varscan2
- CA1 | c.67A>T p.I23F | Missense Mutation (SNP) | VAF 99/184 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as COSV56279932; called by muse, mutect2, varscan2
- CACNA1I | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 58/100 reads (58%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.036); catalogued as COSV60817518; called by muse, mutect2, varscan2
- CACNB2 | c.1283A>C p.K428T (on ENST00000324631 / NM_201596.3; = p.K373T on NM_000724.4) | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56644559; called by muse, mutect2, varscan2
- CAMSAP1 | c.3280G>A p.G1094S | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (1); PolyPhen possibly damaging (0.618); catalogued as COSV56728063; called by muse, mutect2, varscan2
- CCDC110 | c.292C>G p.P98A | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV56870819, COSV56873133; called by muse, mutect2, varscan2
- CCDC190 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV63363582; called by muse, mutect2, varscan2
- CCDC27 | c.65C>A p.P22Q | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.099); catalogued as COSV53902927, COSV99622840; called by muse, mutect2, varscan2
- CCDC88A | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 34/213 reads (16%) | catalogued as COSV99709486; called by muse, mutect2, varscan2
- CCT7 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 56/86 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57823601, COSV99240862; called by muse, mutect2, varscan2
- CD109 | c.111G>T p.R37S | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV54656200; called by muse, mutect2, varscan2
- CD33 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV51800032; called by muse, mutect2, varscan2
- CD5 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100759705; called by muse, mutect2, varscan2
- CDH11 | c.2380G>A p.D794N | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV51775722; called by muse, mutect2, varscan2
- CDH22 | c.1879C>A p.L627I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV64839493; called by muse, mutect2, varscan2
- CDH7 | c.2136G>C p.W712C | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.921); catalogued as COSV59893463; called by muse, mutect2, varscan2
- CEP126 | c.1418G>A p.R473K | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.611); catalogued as COSV54830027, COSV54831424; called by muse, mutect2, varscan2
- CFH | c.593G>A p.W198* | Nonsense Mutation (SNP) | VAF 41/121 reads (34%) | catalogued as CM1512036, COSV62778469; called by muse, mutect2, varscan2
- CHEK2 | c.1297T>A p.Y433N (on ENST00000382580 / NM_001005735.2; = p.Y390N on NM_007194.4) | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60423068, COSV60425518; called by muse, mutect2, varscan2
- CIAPIN1 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV67953605; called by muse, mutect2, varscan2
- CMPK2 | c.1166G>T p.R389L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762036620, COSV56776018, COSV56776038; called by muse, mutect2, varscan2
- COL11A1 | c.1952G>C p.R651P | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62191175, COSV62195443; called by muse, mutect2, varscan2
- COL12A1 | c.8939G>A p.R2980Q | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59406523; called by muse, mutect2, varscan2
- COL24A1 | c.4015G>C p.G1339R | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs937799451, COSV65312617, COSV65313125; called by muse, mutect2, varscan2
- COL4A6 | c.1375G>T p.G459C | Missense Mutation (SNP) | VAF 57/66 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57876334; called by muse, mutect2, varscan2
- COL8A2 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV57443283; called by muse, mutect2, varscan2
- COPG1 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.492); catalogued as COSV59116332; called by muse, mutect2, varscan2
- CPD | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs752689302, COSV56715837; called by muse, mutect2, varscan2
- CR1 | c.953C>A p.P318H (on ENST00000367051; = p.P768H on NM_000651.6) | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.819); catalogued as COSV65462558; called by muse, mutect2, varscan2
- CSF1R | c.2512G>A p.V838I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs690016557, CM1311990, COSV53836780; called by muse, mutect2, varscan2
- CSMD1 | c.8243G>T p.G2748V (on ENST00000520002; = p.G2747V on NM_033225.6) | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59376164; called by muse, mutect2, varscan2
- CTNNAL1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 39/50 reads (78%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV57705306; called by muse, mutect2, varscan2
- CX3CL1 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs200354035, COSV50056833; called by muse, mutect2, varscan2
- CYFIP2 | c.1624T>C p.F542L | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.786); catalogued as COSV59049529; called by muse, mutect2, varscan2
- CYGB | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); catalogued as rs760511803, COSV53151286; called by muse, mutect2, varscan2
- CYP4Z1 | c.208C>A p.H70N | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV61965871, COSV61966430; called by muse, mutect2, varscan2
- DDX23 | c.1172G>T p.R391L | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57285948; called by muse, mutect2, varscan2
- DELE1 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV52006360; called by muse, mutect2, varscan2
- DGKB | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV51790648, COSV51815168; called by muse, mutect2, varscan2
- DHX15 | c.702-1G>A p.X234_splice | Splice Site (SNP) | VAF 17/43 reads (40%) | catalogued as COSV61029075; called by muse, mutect2, varscan2
- DLGAP3 | c.1370C>A p.S457Y | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52397162; called by muse, mutect2, varscan2
- DMRTA1 | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 59/70 reads (84%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV57925354; called by muse, mutect2, varscan2
- DNAH5 | c.5308G>T p.G1770C | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1346242969, COSV54248703; called by muse, mutect2, varscan2
- DNAH5 | c.3977G>A p.S1326N | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV54248712; called by muse, mutect2, varscan2
- DNAH8 | c.720G>T p.L240F | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59476522; called by muse, mutect2, varscan2
- DNAJB6 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.855); catalogued as rs769285457, COSV51099718; called by muse, mutect2, varscan2
- DNMT1 | c.4787T>A p.M1596K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV61583084; called by muse, mutect2, varscan2
- DSCAM | c.5346G>T p.E1782D | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101261778, COSV68035014; called by muse, mutect2, varscan2
- DSG3 | c.1849G>C p.G617R | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57129300; called by muse, mutect2, varscan2
- DTX2 | c.1551G>A p.Q517= | Splice Region (SNP) | VAF 16/30 reads (53%) | catalogued as rs1320218655, COSV56864726; called by muse, mutect2
- DUSP15 | c.364G>A p.A122T (on ENST00000278979 / NM_001320479.1; = p.A125T on NM_080611.4) | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs767032885, COSV54068064; called by muse, mutect2, varscan2
- DYNC1I2 | c.1704G>T p.E568D | Missense Mutation (SNP) | VAF 74/101 reads (73%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV55529429; called by muse, mutect2, varscan2
- DZANK1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.94); catalogued as rs1199741103, COSV52756538; called by muse, mutect2, varscan2
- DZIP1 | c.2099C>G p.P700R (on ENST00000347108; = p.P681R on NM_014934.5) | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.043); catalogued as COSV61267516, COSV61269591; called by muse, mutect2, varscan2
- E4F1 | c.158-1G>A p.X53_splice | Splice Site (SNP) | VAF 15/26 reads (58%) | catalogued as COSV57041118; called by muse, mutect2
- EAPP | c.319T>A p.F107I | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV51653109; called by muse, mutect2, varscan2
- EBF1 | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.027); catalogued as COSV58193024; called by muse, mutect2, varscan2
- EFCAB6 | c.2797G>A p.G933S | Missense Mutation (SNP) | VAF 94/340 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV53071527; called by muse, mutect2, varscan2
- ELP2 | c.1313G>A p.G438E | Missense Mutation (SNP) | VAF 66/128 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60854070; called by muse, mutect2, varscan2
- EP300 | c.2132-1G>A p.X711_splice | Splice Site (SNP) | VAF 30/55 reads (55%) | catalogued as COSV54343552; called by muse, mutect2, varscan2
- EPPK1 | c.3407C>A p.P1136Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs571639648, COSV101599700; called by muse, mutect2
- EQTN | c.874G>T p.V292F | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV66218944, COSV66219426; called by muse, mutect2, varscan2
- ESCO2 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1384840083, COSV59416309; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EVC | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.714); catalogued as COSV53837445; called by muse, mutect2
- EXTL2 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV64473552; called by muse, mutect2, varscan2
- EYS | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1302751436, COSV60998745; called by muse, mutect2, varscan2
- FAM120C | c.944T>C p.L315P | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60262195; called by muse, mutect2, varscan2
- FAM50B | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV66655191; called by muse, mutect2, varscan2
- FBXO7 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56681111; called by muse, mutect2, varscan2
- FETUB | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV54007041; called by muse, mutect2, varscan2
- FLG | c.3947G>C p.R1316T | Missense Mutation (SNP) | VAF 105/249 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as rs767954865, COSV64247852; called by muse, mutect2, varscan2
- FLI1 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1190228942, COSV55647478; called by muse, mutect2, varscan2
- FMN2 | c.3362C>T p.P1121L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.289); catalogued as COSV60427724; called by muse, mutect2, varscan2
- FMR1 | c.1420A>T p.R474* | Nonsense Mutation (SNP) | VAF 46/51 reads (90%) | catalogued as COSV99502820; called by muse, mutect2, varscan2
- FNBP1L | c.1792C>G p.L598V (on ENST00000271234 / NM_001164473.2; = p.L540V on NM_017737.5) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV53096325; called by muse, mutect2, varscan2
- GABRA3 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 56/72 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64804529; called by muse, mutect2, varscan2
- GABRG2 | c.1213C>T p.P405S (on ENST00000361925 / NM_001375343.1; = p.P365S on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as rs377035112; called by muse, mutect2, varscan2
- GAD2 | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV52167047; called by muse, mutect2, varscan2
- GEMIN5 | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1561716242, COSV53558155; called by muse, mutect2, varscan2
- GOLGA5 | c.1852C>T p.Q618* | Nonsense Mutation (SNP) | VAF 51/125 reads (41%) | catalogued as COSV99370584; called by muse, mutect2, varscan2
- GPC2 | c.1513G>T p.G505* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as rs1414676071, COSV99444236; called by muse, mutect2, varscan2
- GPRC5B | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.087); catalogued as rs1167942551, COSV56028559; called by muse, mutect2, varscan2
- GRIK3 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.76); catalogued as rs371290167, COSV66146038; called by muse, mutect2
- GRIK5 | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV53485102; called by muse, mutect2, varscan2
- GRM1 | c.3332A>T p.Y1111F | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV51295405, COSV51391196; called by muse, mutect2, varscan2
- H6PD | c.1213G>T p.G405C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66232170; called by muse, mutect2, varscan2
- HCLS1 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV58859813; called by muse, mutect2, varscan2
- HGD | c.88-1G>A p.X30_splice | Splice Site (SNP) | VAF 62/141 reads (44%) | catalogued as COSV52201052; called by muse, mutect2, varscan2
- HIC2 | c.1753G>T p.G585C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68042828; called by muse, mutect2, varscan2
- HSPA14 | c.100G>C p.V34L | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs1400738130, COSV65685117; called by muse, mutect2, varscan2
- HUWE1 | c.1282T>G p.F428V | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV53362150; called by muse, mutect2, varscan2
- IK | c.1558A>T p.K520* | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | catalogued as COSV100845523; called by muse, mutect2, varscan2
- IPO8 | c.961C>A p.R321S | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs759724163, COSV56245190; called by muse, mutect2, varscan2
- ITGB3 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1415904440, COSV101457501, COSV71385189; called by muse, mutect2, varscan2
- ITPRIPL2 | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV67348055; called by muse, mutect2, varscan2
- KCNH8 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as COSV100108798, COSV60475108; called by muse, mutect2, varscan2
- KCNQ5 | c.1828G>C p.E610Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV59664167, COSV59680799; called by muse, mutect2, varscan2
- KDM6A | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as COSV65044801; called by muse, mutect2, varscan2
- KHDC3L | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 49/101 reads (49%) | catalogued as COSV100951033; called by muse, mutect2, varscan2
- KIAA0100 | c.5631T>A p.N1877K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66495973; called by muse, mutect2, varscan2
- KIF16B | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1311392380, COSV61712533; called by muse, mutect2, varscan2
- KLF13 | c.535G>C p.G179R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100207011; called by muse, mutect2
- KRI1 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs778985203, COSV57265801; called by muse, mutect2, varscan2
- KRTAP1-5 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.067); catalogued as COSV100721406, COSV62624051; called by muse, mutect2, varscan2
- KSR2 | c.497G>T p.W166L | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.06); catalogued as rs1464169194, COSV60393098; called by muse, mutect2, varscan2
- LCTL | c.1310A>G p.N437S | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57182783; called by muse, mutect2, varscan2
- LHX8 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1249851043, COSV99632721; called by muse, mutect2, varscan2
- LIMCH1 | c.2113G>A p.V705M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1248349334, COSV58295283; called by muse, mutect2, varscan2
- LMBR1 | c.453G>C p.L151F | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs763674051, COSV62220149, COSV62222969; called by muse, mutect2, varscan2
- LMTK2 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.243); catalogued as COSV52001066, COSV52003027; called by muse, mutect2, varscan2
- LRIT1 | c.1467G>T p.L489F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.673); catalogued as rs1480269048, COSV64513492; called by muse, mutect2, varscan2
- LRP1B | c.9313G>A p.D3105N | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67222435; called by muse, mutect2, varscan2
- LRP1B | c.1932G>A p.M644I | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as COSV101261693, COSV67269009; called by muse, mutect2, varscan2
- LRP4 | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66135937; called by muse, mutect2, varscan2
- MAGEC1 | c.2224A>T p.S742C | Missense Mutation (SNP) | VAF 70/90 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as COSV53580301; called by muse, mutect2, varscan2
- MAP3K4 | c.4097G>A p.G1366E | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62337905; called by muse, mutect2, varscan2
- MFHAS1 | c.3020G>A p.R1007K | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); catalogued as COSV52286556; called by muse, mutect2, varscan2
- MMP24 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55772784; called by muse, mutect2, varscan2
- MROH5 | c.3548C>T p.A1183V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1490285041, COSV100266985; called by muse, mutect2, varscan2
- MST1R | c.2851G>T p.D951Y | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV56573173; called by muse, mutect2, varscan2
- MUC4 | c.2572C>A p.P858T | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.65); catalogued as COSV62189520; called by muse, mutect2, varscan2
- MYH15 | c.2101G>A p.V701I | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.233); catalogued as COSV56318540; called by muse, mutect2, varscan2
- MYO6 | c.1612C>A p.P538T | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV64121156; called by muse, mutect2, varscan2
- NBEA | c.1437G>C p.Q479H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV59818489; called by muse, mutect2, varscan2
- NEK10 | c.3307C>A p.H1103N | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV55364301; called by muse, mutect2, varscan2
- NEK10 | c.2503C>T p.H835Y | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV55364325; called by muse, mutect2, varscan2
- NEK11 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53910294; called by muse, mutect2, varscan2
- NFATC1 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.118); catalogued as COSV53708371; called by muse, mutect2, varscan2
- NID2 | c.2400G>C p.V800= | Splice Region (SNP) | VAF 30/65 reads (46%) | catalogued as COSV53492384, COSV53502141; called by muse, mutect2
- NLRP12 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.31); catalogued as COSV60754000; called by muse, mutect2, varscan2
- NLRP7 | c.692G>T p.W231L | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.324); catalogued as COSV60181196; called by muse, mutect2, varscan2
- NOC3L | c.515A>G p.D172G | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV64930537; called by muse, mutect2, varscan2
- NOP53 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV55883029; called by muse, mutect2, varscan2
- NOP9 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.332); catalogued as COSV51867968; called by muse, mutect2, varscan2
- NOS1 | c.2866G>C p.E956Q | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.778); catalogued as COSV57620425; called by muse, mutect2, varscan2
- NOX4 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.119); catalogued as COSV54463481, COSV99632350; called by muse, mutect2, varscan2
- NPC1L1 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs776868051, COSV56929771; called by muse, mutect2, varscan2
- NRAP | c.2584A>C p.K862Q (on ENST00000359988 / NM_001322945.2; = p.K827Q on NM_006175.4) | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV63493556; called by muse, mutect2, varscan2
- NREP | c.8A>C p.Y3S | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV57406127; called by muse, mutect2, varscan2
- NRXN1 | c.3940C>G p.Q1314E | Missense Mutation (SNP) | VAF 114/187 reads (61%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV60519934; called by muse, mutect2, varscan2
- NUDT7 | c.659T>A p.L220* | Nonsense Mutation (SNP) | VAF 34/43 reads (79%) | catalogued as COSV51745707, COSV99215866; called by muse, mutect2, varscan2
- OBSCN | c.860A>G p.Y287C | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs773872819, COSV52822444; called by muse, mutect2, varscan2
- OBSCN | c.15136G>A p.A5046T | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs777695698, COSV52822475; called by muse, mutect2
- OCA2 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1192052771, COSV62355836; called by muse, mutect2, varscan2
- OCA2 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.024); catalogued as COSV62356765; called by muse, mutect2, varscan2
- OMG | c.907A>C p.I303L | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV55988600; called by muse, mutect2, varscan2
- OR2AG2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.84); PolyPhen benign (0.02); catalogued as COSV58456084; called by muse, mutect2, varscan2
- OR2G2 | c.515G>A p.C172Y | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60742187; called by muse, mutect2, varscan2
- OR51Q1 | c.626T>G p.I209S | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.345); catalogued as COSV56180444; called by muse, mutect2
- OR5D13 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs777852254, COSV100686654, COSV62332645; called by muse, mutect2, varscan2
- OR5H15 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.988); catalogued as rs753978686, COSV100736593; called by muse, mutect2, varscan2
- OR6K6 | c.1020G>C p.W340C (on ENST00000368144; = p.W316C on NM_001005184.1) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV63743659, COSV63744815; called by muse, mutect2, varscan2
- OSR2 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52558606; called by muse, mutect2, varscan2
- OTOGL | c.2496T>A p.D832E (on ENST00000547103; = p.D823E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1283862982, COSV72007399; called by muse, mutect2, varscan2
- OXER1 | c.1055C>A p.P352H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54311089, COSV54312842; called by muse, mutect2, varscan2
- PADI2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs201884124, COSV64946580; called by muse, mutect2, varscan2
- PAK6 | c.1906G>T p.E636* | Nonsense Mutation (SNP) | VAF 39/99 reads (39%) | catalogued as COSV99544039; called by muse, mutect2, varscan2
- PAPPA2 | c.1964C>A p.T655N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as rs1409382432, COSV62785516; called by muse, mutect2, varscan2
- PCDHA8 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65332044; called by muse, mutect2, varscan2
- PCDHB6 | c.1226G>A p.R409K | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV50724650; called by muse, mutect2, varscan2
- PCDHGA2 | c.2266G>T p.E756* | Nonsense Mutation (SNP) | VAF 54/140 reads (39%) | catalogued as COSV53930831, COSV99527854; called by muse, mutect2, varscan2
- PCLO | c.9541G>T p.V3181F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as COSV61662050, COSV99067640; called by muse, mutect2, varscan2
- PCYOX1L | c.1015G>T p.G339C | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51005126; called by muse, mutect2, varscan2
- PDGFRB | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV55809571; called by muse, mutect2, varscan2
- PDS5B | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV59733665; called by muse, mutect2, varscan2
- PDS5B | c.4279A>G p.T1427A | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV59733707; called by muse, mutect2, varscan2
- PELI3 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1240657942, COSV100291879, COSV57857647; called by muse, mutect2, varscan2
- PEX5L | c.268A>G p.K90E | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as COSV55850393; called by muse, mutect2, varscan2
- PHF8 | c.182T>A p.M61K (on ENST00000357988 / NM_001184896.1; = p.M25K on NM_015107.3) | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100153656; called by muse, varscan2
- PHRF1 | c.2975G>T p.R992L (on ENST00000264555 / NM_001286581.2; = p.R991L on NM_020901.4) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.145); catalogued as COSV52761973; called by muse, mutect2
- PI4KA | c.3278G>T p.G1093V | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.235); catalogued as COSV55421720; called by muse, mutect2, varscan2
- PIGR | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.118); catalogued as rs370527545; called by muse, mutect2, varscan2
- PKHD1 | c.9799C>A p.H3267N | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.295); catalogued as COSV61892556; called by muse, mutect2, varscan2
- POSTN | c.2335T>A p.L779M | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as COSV65714443; called by muse, mutect2, varscan2
- POTEA | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs1418564508; called by muse, mutect2, varscan2
- PPM1K | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55797738; called by muse, mutect2, varscan2
- PPM1N | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV99838613; called by muse, mutect2
- PRB4 | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.183); catalogued as COSV54399998; called by muse, mutect2
- PRDM11 | c.448G>T p.G150C (on ENST00000530656 / NM_001359633.1; = p.G116C on NM_001256695.1) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55443298; called by muse, mutect2, varscan2
- PREX1 | c.4816C>A p.H1606N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64256279; called by muse, mutect2, varscan2
- PRKG2 | c.965C>G p.T322S | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as COSV52331021; called by muse, mutect2, varscan2
- PRSS1 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 72/116 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs144403091, CM011004, COSV61192213; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSG6 | c.1012C>G p.P338A | Missense Mutation (SNP) | VAF 77/195 reads (39%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.93); catalogued as COSV51837064; called by muse, mutect2, varscan2
- PTAR1 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1246931231, COSV61209512; called by muse, mutect2, varscan2
- PTBP2 | c.1126G>T p.V376L (on ENST00000426398 / NM_001300986.2; = p.V368L on NM_021190.4) | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs1369824468, COSV64626344; called by muse, mutect2, varscan2
- PTPN1 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63298900; called by muse, mutect2, varscan2
- RABL2B | c.686G>C p.*229Sext*23 | Nonstop Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100711439; called by muse, mutect2, varscan2
- RAD54L2 | c.3364A>G p.T1122A | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772061425, COSV56581207; called by muse, mutect2, varscan2
- RALGAPB | c.2903-1G>A p.X968_splice | Splice Site (SNP) | VAF 16/36 reads (44%) | catalogued as COSV53443489; called by muse, mutect2, varscan2
- RBM48 | c.51G>C p.Q17H | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV50414743; called by muse, mutect2, varscan2
- RFC1 | c.3427G>A p.G1143R (on ENST00000381897 / NM_001363496.2; = p.G1142R on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.999); catalogued as COSV56469467; called by muse, mutect2, varscan2
- RGS10 | c.454G>A p.E152K (on ENST00000369101; = p.E146K on NM_002925.3) | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated (0.62); PolyPhen benign (0.036); catalogued as COSV64862580; called by muse, mutect2, varscan2
- RGS18 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | catalogued as COSV100817623; called by muse, mutect2, varscan2
- RIF1 | c.2063A>G p.N688S | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as COSV54623284; called by muse, mutect2, varscan2
- RLF | c.1714C>G p.H572D | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65653064; called by muse, mutect2, varscan2
- RPS6KA5 | c.1124A>T p.Y375F | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.895); catalogued as rs1177626577, COSV56225008; called by muse, mutect2, varscan2
- RRP8 | c.634C>G p.P212A | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs757940157, COSV54450638; called by muse, mutect2, varscan2
- RSC1A1 | c.1284A>T p.K428N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV60781323; called by muse, mutect2, varscan2
- SAA2-SAA4 | c.253A>T p.I85F | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as rs760357826, COSV53448981; called by muse, mutect2, varscan2
- SALL1 | c.2882C>T p.S961F | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.564); catalogued as rs148016347, COSV51760789; called by muse, mutect2, varscan2
- SAMD3 | c.384-1G>A p.X128_splice | Splice Site (SNP) | VAF 14/26 reads (54%) | catalogued as COSV60777553; called by muse, mutect2, varscan2
- SEC31B | c.2188G>A p.G730S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as rs144968144; called by muse, mutect2, varscan2
- SERTAD2 | c.761C>G p.S254C | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57640311, COSV57641177; called by muse, mutect2, varscan2
- SGIP1 | c.343A>T p.K115* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as COSV99389959; called by muse, mutect2, varscan2
- SGPL1 | c.1158C>G p.I386M | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV64592387; called by muse, mutect2, varscan2
- SH2D3A | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55588424; called by muse, mutect2, varscan2
- SHF | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as COSV52052399; called by muse, mutect2, varscan2
- SHPRH | c.1712G>A p.R571K | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV51616712; called by muse, mutect2, varscan2
- SI | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.103); catalogued as COSV52298436; called by muse, mutect2, varscan2
- SIGLEC7 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 95/193 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.036); catalogued as rs1488093583, COSV58317638; called by muse, mutect2, varscan2
- SIRPB1 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV53540566; called by muse, mutect2, varscan2
- SLC12A6 | c.317-1G>A p.X106_splice (on ENST00000354181 / NM_001365088.1; = p.X55_splice on NM_005135.2) | Splice Site (SNP) | VAF 18/52 reads (35%) | catalogued as COSV51631181; called by mutect2, varscan2
- SLC22A16 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1410135030, COSV57933968; called by muse, mutect2, varscan2
- SLC25A41 | c.272C>A p.A91D | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV51196271; called by muse, mutect2, varscan2
- SLC7A1 | c.702C>G p.N234K | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV66331747; called by muse, mutect2, varscan2
- SLC8A3 | c.1654G>C p.V552L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63523305, COSV63525958; called by muse, mutect2, varscan2
- SLFN11 | c.1040G>A p.W347* | Nonsense Mutation (SNP) | VAF 38/99 reads (38%) | catalogued as COSV100390246; called by muse, mutect2, varscan2
- SMARCA4 | c.3088G>T p.G1030C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV60807254; called by muse, mutect2, varscan2
- SNX7 | c.255C>G p.I85M | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as COSV60271626; called by muse, mutect2, varscan2
- SPIRE1 | c.1172T>G p.I391S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV59161891; called by muse, mutect2, varscan2
- SSH3 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs754429768, COSV57386564; called by muse, mutect2, varscan2
- STAG1 | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52622484; called by muse, mutect2, varscan2
- SUPT6H | c.2636C>T p.S879F | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.264); catalogued as COSV58931097; called by muse, mutect2, varscan2
- SURF2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs1182952634, COSV64332277, COSV64332613; called by muse, mutect2, varscan2
- SYTL5 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV52899281; called by muse, mutect2, varscan2
- TALDO1 | c.878C>G p.S293C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as COSV59798457; called by muse, mutect2, varscan2
- TAOK3 | c.1330G>T p.V444F | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV66827551; called by muse, mutect2, varscan2
- TGFB1I1 | c.50A>C p.H17P | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV62359100; called by muse, mutect2, varscan2
- TGM5 | c.10+2T>A p.X4_splice | Splice Site (SNP) | VAF 25/63 reads (40%) | catalogued as COSV55011997; called by muse, mutect2, varscan2
- THOC5 | c.1648C>G p.L550V | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV63800907; called by muse, mutect2, varscan2
- TIMD4 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV50855627; called by muse, mutect2, varscan2
- TLE6 | c.1366G>T p.E456* (on ENST00000246112 / NM_001143986.2; = p.E333* on NM_024760.3) | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV99857813; called by muse, mutect2, varscan2
- TMEM61 | c.380T>C p.V127A | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV64873890; called by muse, mutect2, varscan2
- TMEM65 | c.472G>C p.A158P | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52632101; called by muse, mutect2, varscan2
- TNXB | c.7934C>T p.P2645L (on ENST00000647633; = p.P2398L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1444901496, COSV64487990; called by muse, mutect2, varscan2
- TOPORS | c.2017C>A p.R673S | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.055); catalogued as COSV62117107, COSV62117485; called by muse, mutect2, varscan2
- TPP2 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65754656; called by muse, mutect2, varscan2
- TRANK1 | c.2779C>T p.R927W | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs755918039, COSV57139510; called by muse, mutect2, varscan2
- TRAP1 | c.248-1G>A p.X83_splice | Splice Site (SNP) | VAF 16/42 reads (38%) | catalogued as COSV55918320; called by muse, mutect2, varscan2
- TRAPPC9 | c.2947G>A p.G983S | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.371); catalogued as rs770440531, COSV66894992, COSV66905859; called by muse, mutect2, varscan2
- TTC3 | c.2026C>T p.R676C | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs747475282, COSV61295400; called by muse, mutect2, varscan2
- TTN | c.49750G>C p.G16584R (on ENST00000591111; = p.G9160R on NM_003319.4) | Missense Mutation (SNP) | VAF 94/136 reads (69%) | PolyPhen possibly damaging (0.9); catalogued as COSV60305944, COSV60349257; called by muse, mutect2, varscan2
- TULP3 | c.379C>A p.R127S | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.021); catalogued as COSV101237543, COSV68118639; called by muse, mutect2
- TULP4 | c.1904C>T p.P635L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV65580297; called by muse, mutect2, varscan2
- UBAP2L | c.2626G>T p.A876S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.168); catalogued as COSV55180358; called by muse, mutect2, varscan2
- VCAN | c.9880G>T p.V3294F | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54115359; called by muse, mutect2, varscan2
- WDHD1 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as rs1392501288, COSV100777511; called by muse, mutect2, varscan2
- WNT2B | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV56676690; called by muse, mutect2, varscan2
- YTHDF2 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 40/97 reads (41%) | catalogued as COSV100863591; called by muse, mutect2, varscan2
- ZAN | c.3332C>T p.P1111L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); catalogued as rs1361365072, COSV61815399; called by muse, mutect2, varscan2
- ZBTB21 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60405553; called by muse, mutect2, varscan2
- ZC3H4 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs1451345178, COSV53416726; called by muse, mutect2, varscan2
- ZFHX4 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV51492712; called by muse, mutect2, varscan2
- ZFP82 | c.135G>C p.L45= | Splice Region (SNP) | VAF 35/80 reads (44%) | catalogued as COSV67566635; called by muse, mutect2, varscan2
- ZNF142 | c.4339C>T p.R1447W (on ENST00000411696 / NM_001379660.1; = p.R1247W on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/66 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs1030661078, COSV68745392; called by muse, mutect2, varscan2
- ZNF396 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs949401279, COSV60474247; called by muse, mutect2, varscan2
- ZNF521 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64131319, COSV64131525; called by muse, mutect2, varscan2
- ZNF543 | c.11C>A p.S4* | Nonsense Mutation (SNP) | VAF 20/31 reads (65%) | catalogued as COSV100386553; called by muse, mutect2, varscan2
- ZNF597 | c.614T>C p.I205T | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV57085507; called by muse, mutect2, varscan2
- ZNF607 | c.120C>G p.D40E | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV62206296; called by muse, mutect2, varscan2
- ZNF681 | c.749G>T p.R250I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV101267397, COSV68075523; called by muse, mutect2
- ZNF714 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.165); catalogued as COSV52515262; called by muse, mutect2, varscan2
- ZNF830 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV58491629; called by muse, mutect2, varscan2
- ZNRF3 | c.794G>A p.R265K (on ENST00000544604 / NM_001206998.2; = p.R165K on NM_032173.3) | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.083); catalogued as COSV60437999; called by muse, mutect2, varscan2
- ZSCAN25 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764460768, COSV53554434; called by muse, mutect2, varscan2
- APOB | c.742A>T p.T248S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.067); called by muse, mutect2
- IL16 | c.436del p.C146Afs*9 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | called by mutect2, pindel, varscan2
- PCDH7 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- SLC12A6 | c.219dup p.A74Cfs*7 | Frame Shift Ins (INS) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- AC004922.1 | c.582G>A p.L194= | Silent (SNP) | VAF 47/129 reads (36%) | catalogued as COSV53558992; called by muse, mutect2, varscan2
- ACBD5 | c.609A>G p.E203= (on ENST00000375888 / NM_001352568.1; = p.E194= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV65521061; called by muse, mutect2, varscan2
- ADGRL3 | c.3363G>A p.L1121= (on ENST00000506720 / NM_001322402.2; = p.L1053= on NM_015236.6) | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV72230814; called by muse, mutect2, varscan2
- ALK | c.1482G>A p.L494= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as COSV66587503; called by muse, mutect2, varscan2
- AMIGO1 | c.45G>A p.P15= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs769716146, COSV100880941; called by muse, varscan2
- ANKRD13C | c.510C>G p.V170= | Silent (SNP) | VAF 51/122 reads (42%) | catalogued as rs369115273; called by muse, mutect2, varscan2
- ASCC3 | c.172C>T p.L58= | Silent (SNP) | VAF 51/136 reads (38%) | catalogued as COSV100225709, COSV61233194; called by muse, mutect2, varscan2
- AUTS2 | c.2956C>A p.R986= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100714568, COSV61416720; called by muse, mutect2
- AVL9 | c.825A>G p.G275= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as COSV59468830; called by muse, mutect2, varscan2
- BCHE | c.306A>T p.P102= | Silent (SNP) | VAF 71/153 reads (46%) | catalogued as COSV52261743; called by muse, mutect2, varscan2
- BNC2 | c.2040G>A p.E680= | Silent (SNP) | VAF 30/39 reads (77%) | catalogued as COSV66156167; called by muse, mutect2, varscan2
- C1orf174 | c.201G>A p.V67= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as COSV64365985; called by muse, mutect2, varscan2
- CCDC8 | c.942G>A p.G314= | Silent (SNP) | VAF 50/135 reads (37%) | catalogued as COSV56774862; called by muse, mutect2, varscan2
- CCHCR1 | c.2145G>A p.V715= | Silent (SNP) | VAF 110/250 reads (44%) | catalogued as COSV52536503; called by muse, mutect2, varscan2
- CDH19 | c.579C>A p.G193= | Silent (SNP) | VAF 50/87 reads (57%) | catalogued as rs763770985, COSV50974409; called by muse, mutect2, varscan2
- CFAP77 | c.954C>T p.T318= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as rs1409503938, COSV58016404; called by muse, mutect2, varscan2
- CFHR2 | c.654C>T p.N218= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs752501844, COSV66382065; called by muse, mutect2, varscan2
- CHPF | c.810C>T p.I270= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV60536453, COSV99704784; called by muse, mutect2, varscan2
- CNTN1 | c.2817A>G p.G939= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV61644945; called by muse, mutect2, varscan2
- CPA3 | c.1104C>T p.D368= | Silent (SNP) | VAF 70/162 reads (43%) | catalogued as COSV56047122; called by muse, mutect2, varscan2
- CSPG5 | c.288C>T p.T96= | Silent (SNP) | VAF 26/37 reads (70%) | catalogued as rs755673769, COSV53133281; called by muse, mutect2, varscan2
- CTNND2 | c.2703C>A p.L901= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV58890228, COSV58936861; called by muse, mutect2, varscan2
- DLST | c.828C>G p.L276= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV53167767; called by muse, mutect2, varscan2
- DNAH8 | c.9402G>A p.V3134= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV59476556; called by muse, mutect2, varscan2
- DST | c.20208A>C p.G6736= (on ENST00000361203 / NM_001374722.1; = p.G4433= on NM_015548.5) | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV55036964; called by muse, mutect2, varscan2
- EGFR | c.2781G>A p.L927= | Silent (SNP) | VAF 34/46 reads (74%) | catalogued as COSV51841535; called by muse, mutect2, varscan2
- EIF3A | c.3870A>G p.R1290= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as COSV64963144; called by muse, varscan2
- FAM149A | c.888G>A p.G296= (on ENST00000356371 / NM_001367768.2; = p.G5= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as COSV57030123; called by muse, mutect2, varscan2
- FAM237A | c.384G>T p.A128= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as COSV101405557; called by muse, mutect2, varscan2
- FAT2 | c.11883G>A p.K3961= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV55828371; called by muse, mutect2, varscan2
- FAT3 | c.2694C>T p.A898= | Silent (SNP) | VAF 61/134 reads (46%) | catalogued as rs1429315955, COSV53166591; called by muse, mutect2, varscan2
- GALK2 | c.630G>A p.L210= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs1232020956, COSV59105012; called by muse, mutect2, varscan2
- GOLGB1 | c.3087C>T p.L1029= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as COSV61470360; called by muse, mutect2, varscan2
- GON7 | c.177G>T p.R59= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV50151245; called by muse, mutect2, varscan2
- GSTT2B | c.734G>A p.*245= | Silent (SNP) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- HDC | c.1395T>C p.N465= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as COSV51079883; called by muse, mutect2, varscan2
- HIVEP3 | c.1422C>G p.A474= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV56022568; called by muse, mutect2, varscan2
- HLX | c.138C>T p.I46= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs752408913, COSV65045350; called by muse, mutect2, varscan2
- HMCN1 | c.5943C>A p.A1981= | Silent (SNP) | VAF 55/105 reads (52%) | catalogued as COSV54936221; called by muse, mutect2, varscan2
- IGKV2-30 | c.292C>T p.L98= | Silent (SNP) | VAF 49/216 reads (23%) | called by muse, mutect2, varscan2
- JUP | c.1434C>G p.L478= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV60279550; called by muse, mutect2, varscan2
- KCNK3 | c.531C>A p.A177= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV57194484; called by muse, mutect2, varscan2
- KCNK9 | c.198C>T p.I66= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV57287635; called by muse, mutect2, varscan2
- KRT77 | c.1077C>A p.T359= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100526869; called by muse, mutect2, varscan2
- KRTAP24-1 | c.711C>T p.T237= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs1307494865, COSV61090080; called by muse, mutect2, varscan2
- LCE1E | c.270C>T p.P90= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV64220052; called by muse, mutect2, varscan2
- LMLN | c.681C>T p.N227= | Silent (SNP) | VAF 64/151 reads (42%) | catalogued as COSV57604614; called by muse, mutect2, varscan2
- LMO7 | c.2163G>A p.Q721= (on ENST00000357063; = p.Q402= on NM_005358.5) | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as COSV58547261; called by muse, mutect2, varscan2
- LRRC41 | c.741C>T p.L247= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV58442138; called by muse, mutect2, varscan2
- MIER2 | c.1326G>A p.L442= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1221808783; called by muse, mutect2
- MUC16 | c.7548C>A p.A2516= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs1400561961, COSV67489726; called by muse, mutect2, varscan2
- MUC17 | c.4854T>C p.G1618= | Silent (SNP) | VAF 92/276 reads (33%) | catalogued as COSV60301364; called by muse, mutect2, varscan2
- MYH9 | c.48C>T p.F16= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV53392463; called by muse, mutect2, varscan2
- NAV1 | c.2820G>C p.R940= | Silent (SNP) | VAF 78/219 reads (36%) | catalogued as rs1459276446, COSV55225155; called by muse, mutect2, varscan2
- NKPD1 | c.2397C>A p.A799= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs1361300694, COSV55527199; called by muse, mutect2, varscan2
- NLRP2 | c.747G>A p.E249= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV54759699; called by muse, mutect2, varscan2
- NLRP3 | c.867G>A p.V289= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV60230319, COSV60231268; called by muse, mutect2, varscan2
- NOS3 | c.2679C>T p.L893= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV52495072; called by muse, mutect2, varscan2
- NUDT16L1 | c.36C>T p.I12= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs562874537, COSV99273606; called by muse, varscan2
- OR51F1 | c.528T>C p.Y176= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV58580694; called by muse, mutect2, varscan2
- OR5L1 | c.903C>T p.L301= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV61735255; called by muse, mutect2, varscan2
- OTUD7B | c.1335C>G p.A445= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV64917651; called by muse, mutect2, varscan2
- PANX3 | c.189G>A p.P63= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as rs761575653, COSV52513650, COSV52513931; called by muse, mutect2, varscan2
- PCDHGA12 | c.48G>A p.L16= | Silent (SNP) | VAF 48/90 reads (53%) | catalogued as COSV52766251; called by muse, mutect2, varscan2
- PCDHGA9 | c.1368C>T p.S456= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs577477279, COSV53986613; called by muse, mutect2, varscan2
- PCSK2 | c.384G>A p.K128= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV52742255; called by muse, mutect2, varscan2
- PDGFRB | c.372C>G p.T124= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV55809559; called by muse, mutect2, varscan2
- PKDREJ | c.5184C>T p.I1728= | Silent (SNP) | VAF 33/120 reads (28%) | catalogued as rs780613353, COSV53552696; called by muse, mutect2, varscan2
- PLAA | c.234C>T p.D78= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV68305519; called by muse, mutect2, varscan2
- PLCXD3 | c.747G>T p.L249= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV60617037; called by muse, mutect2, varscan2
- POMGNT2 | c.555G>T p.L185= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV60954548; called by muse, mutect2, varscan2
- PRIMA1 | c.384T>C p.N128= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV60265462; called by muse, mutect2, varscan2
- PROSER1 | c.261T>A p.L87= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as COSV61489392; called by muse, mutect2, varscan2
- PRPF31 | c.297G>C p.L99= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV58086869; called by muse, mutect2, varscan2
- PTPRH | c.2685C>A p.P895= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV54749509; called by muse, mutect2, varscan2
- REV3L | c.5493C>T p.D1831= | Silent (SNP) | VAF 58/158 reads (37%) | catalogued as rs201671524, COSV62615738, COSV62621918; called by muse, mutect2, varscan2
- RGS5 | c.480C>T p.A160= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV58353936; called by muse, mutect2, varscan2
- RIMS3 | c.492C>T p.I164= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV65505337; called by muse, mutect2, varscan2
- RNF17 | c.1386C>T p.D462= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV55049838; called by muse, mutect2, varscan2
- RPAP2 | c.1758C>T p.T586= | Silent (SNP) | VAF 60/147 reads (41%) | catalogued as COSV72101659; called by muse, mutect2, varscan2
- RRP7A | c.618G>T p.V206= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs756529214, COSV100543680; called by muse, mutect2, varscan2
- SBF2 | c.468T>C p.I156= | Silent (SNP) | VAF 59/177 reads (33%) | catalogued as COSV56309619; called by muse, mutect2, varscan2
- SEMA5B | c.1822C>A p.R608= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV52102286, COSV99533536; called by muse, mutect2, varscan2
- SERPINA4 | c.321C>T p.F107= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV54071436; called by muse, mutect2, varscan2
- SHPK | c.1044C>T p.S348= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV56650291; called by muse, mutect2, varscan2
- SIDT1 | c.966G>A p.L322= | Silent (SNP) | VAF 50/156 reads (32%) | catalogued as rs139102005; called by muse, mutect2, varscan2
- SLAMF1 | c.765G>A p.V255= | Silent (SNP) | VAF 68/182 reads (37%) | catalogued as COSV52499054, COSV52499511; called by muse, mutect2, varscan2
- SLC17A2 | c.1041G>A p.V347= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs778550324, COSV55354632; called by muse, mutect2, varscan2
- SLC26A3 | c.1911C>G p.L637= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as COSV60642385, COSV60643328; called by muse, mutect2, varscan2
- SLC8A3 | c.1911G>C p.V637= (on ENST00000381269 / NM_183002.3; = p.V631= on NM_182932.3) | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV53692321; called by muse, mutect2, varscan2
- SPANXN3 | c.108C>A p.A36= | Silent (SNP) | VAF 39/49 reads (80%) | catalogued as rs199758045, COSV65140788; called by muse, mutect2, varscan2
- SPATA20 | c.1851C>T p.G617= (on ENST00000356488 / NM_001258372.1; = p.G633= on NM_022827.4) | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs761090951, COSV50069638; called by muse, mutect2, varscan2
- SPTAN1 | c.2925C>G p.L975= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as COSV63989584; called by muse, mutect2, varscan2
- SUSD1 | c.1413G>A p.V471= | Silent (SNP) | VAF 55/77 reads (71%) | catalogued as COSV62585307; called by muse, mutect2, varscan2
- TCHHL1 | c.1455C>T p.N485= | Silent (SNP) | VAF 79/179 reads (44%) | catalogued as rs150195731, COSV64285426; called by muse, mutect2, varscan2
- TEAD2 | c.576A>T p.P192= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV100246386; called by muse, varscan2
- TENM3 | c.2016T>A p.T672= | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as COSV69317792; called by muse, mutect2, varscan2
- TMEM215 | c.216C>T p.N72= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs776047243, COSV61363468; called by muse, mutect2, varscan2
- TSPAN11 | c.432C>T p.A144= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV53821297; called by muse, mutect2, varscan2
- TSPAN4 | c.123C>T p.F41= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs140041258; called by muse, mutect2, varscan2
- TSSK4 | c.864C>A p.I288= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV55304954; called by muse, mutect2, varscan2
- TTN | c.22705C>T p.L7569= (on ENST00000591111; = p.L6642= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs1255251133, COSV60306007; called by muse, mutect2, varscan2
- USP22 | c.903C>T p.F301= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV54948694; called by muse, mutect2, varscan2
- USP49 | c.654C>T p.D218= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1446342409, COSV51895884; called by muse, mutect2
- VIPAS39 | c.624G>C p.L208= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV58941991; called by muse, mutect2, varscan2
- VSTM4 | c.894C>T p.H298= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as rs1409647568, COSV60529433; called by muse, mutect2, varscan2
- ZBTB20 | c.1455C>T p.S485= (on ENST00000474710 / NM_001164342.2; = p.S412= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV61866316; called by muse, mutect2, varscan2
- ZNF609 | c.3618C>T p.P1206= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV58589353; called by muse, mutect2, varscan2
- ZSCAN5A | c.960C>T p.G320= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV54231279; called by muse, mutect2, varscan2
- ZYG11B | c.306C>T p.F102= | Silent (SNP) | VAF 52/128 reads (41%) | catalogued as COSV53756677; called by muse, mutect2, varscan2
- CSNK1E | c.886-2114C>T | Intron (SNP) | VAF 19/79 reads (24%) | catalogued as rs576535223, COSV63292088; called by muse, mutect2, varscan2
- DEFB106B | c.-1C>T | 5'UTR (SNP) | VAF 16/30 reads (53%) | catalogued as rs1397408644, COSV100128843; called by mutect2, varscan2
- DNAH8 | c.-41-4547C>T | Intron (SNP) | VAF 5/14 reads (36%) | catalogued as rs368460226, COSV59492992; called by muse, varscan2
- DPP6 | c.627+21075C>G | Intron (SNP) | VAF 63/126 reads (50%) | catalogued as COSV100122286; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7470G>A | Intron (SNP) | VAF 41/108 reads (38%) | catalogued as COSV63393912; called by muse, mutect2, varscan2
- GCSH | chr16:81101209 C>T | 5'Flank (SNP) | VAF 14/40 reads (35%) | catalogued as rs1156637139; called by muse, mutect2, varscan2
- HERC2P3 | n.1995C>T | RNA (SNP) | VAF 9/57 reads (16%) | called by mutect2, varscan2
- IFNA10 | c.-1A>C | 5'UTR (SNP) | VAF 22/27 reads (81%) | catalogued as COSV99497297; called by muse, mutect2, varscan2
- MAGED2 | c.1272-206G>T | Intron (SNP) | VAF 87/110 reads (79%) | catalogued as rs767454532, COSV99514320; called by muse, mutect2, varscan2
- RLF | c.-1G>A | 5'UTR (SNP) | VAF 7/11 reads (64%) | catalogued as rs1179661370, COSV101034905; called by muse, mutect2, varscan2
- RPL4 | c.422-148G>A | Intron (SNP) | VAF 34/114 reads (30%) | catalogued as rs370840729; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 7/36 reads (19%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
